Gene-level copy-number profile of tumor specimen TCGA-CV-5435-01A from TCGA case TCGA-CV-5435, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 57.3 years (20,926 days).
Specimen TCGA-CV-5435-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a08bc551-4295-408a-bd94-fd5c37cccac0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5435-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c0cf3bb6-7101-4c73-a3b5-923dd3f23142

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,580; copy number 2: 8,244; copy number 3: 12,120; copy number 4: 29,546; copy number 5: 4,222; copy number 6: 2,323; copy number 8: 1,766; copy number 10: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5435-01A-01D-1682-01): tumor purity 0.66, ploidy 3.71, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 19 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,987,075–33,512,743, 19 genes, copy number 10 (within-gene range 2–10): AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1.

Autosomal genes at a single copy (total copy number 1): 654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
